Surgical pathology report (de-identified scan), TCGA case TCGA-85-8070, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8070-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

		OpenClinica ID	Gross Description	Microscopic Description	Diagnosis Details	Comments
						LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 3.5 x 3.5 x 3.5 cm Histologic type: Squamous cell carcinoma Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 0/2 positive for metastasis (Regional 0/2) Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo

[page 2 of 2]
Formatted Path Report	Laterality	Excision date
Left-upper		

Source: NCI Genomic Data Commons file 23b96099-7da4-41f0-bf6d-819ce56367f8 (TCGA-85-8070.F9544640-64F9-40C7-AF40-001E509C4897.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).